Somatic mutation profile of tumor specimen MP2PRT-PASKLF-TMP1-A (aliquot MP2PRT-PASKLF-TMP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PASKLF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (598 days).
Specimen MP2PRT-PASKLF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18212996-38fa-4bde-85bb-b8e2feff205a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKLF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKLF-NB1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b01040a6-3bcb-47d5-8ea6-b2e2eea17226

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 146/476 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MYRFL | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 143/412 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs1030864191; called by muse, mutect2, varscan2
- SRRM4 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 454/1113 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.345); catalogued as rs1384633476, COSV57409524; called by muse, varscan2
- RYR3 | c.11082G>T p.L3694F (on ENST00000389232; = p.L3695F on NM_001036.6) | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CCDC80 | c.888C>T p.D296= | Silent (SNP) | VAF 236/552 reads (43%) | catalogued as rs754534040, COSV52814753; called by muse, mutect2, varscan2
- ISLR | c.273C>T p.A91= | Silent (SNP) | VAF 307/747 reads (41%) | catalogued as rs763412809; called by muse, varscan2
- OOEP | c.285C>T p.T95= | Silent (SNP) | VAF 297/675 reads (44%) | called by muse, mutect2, varscan2
